Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3LT, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3LT-01A (Primary Tumor).

[page 1 of 2]
Patient:

Physician:

CC:

Patient Address:

Date of Report:

....

Clinical Diagnosis & History:

Specimens Submitted:

- 1: Right arm mass
- 2: Right arm mass

DIAGNOSIS:

1. Soft tissue, right arm, mass, excision:
- Residual Dedifferentiated liposarcoma, high grade.
- The tumor is encapsulated and measures 5.0 cm in greatest dimension.
- Dedifferentiated component is a high-grade spindle cell sarcoma.
- Margins of resection are negative for tumor.
- Skin and subcutaneous tissue with prior procedure related changes.
2. Soft tissue, right arm, excision:
- Benign adipose tissue with focal fibrosis and foreign-body reaction.
- No definite evidence of malignancy.

Note: The patient's prior specimen was reviewed.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.The specimen is received fresh, labeled "right arm mass, short stitch proximal, long stitch distal" and consists of an ellipse of skin measuring 11.5 x 7.3 cm with a linear scar measuring 7.5 cm with attached soft tissue measuring 17 x 7 cm (thickness). A 5 x 3.5 x 3 cm mass is present in the

** Continued on next page **

1CD-0-3
dedifferentiated liposarcoma 8858/3
Site: arm, NOS 649.1
hw
12/23/11

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

on [REDACTED]

----- Page 2 of 2
soft tissue, surrounded by a thin capsule and abutting the deep margin of resection. The mass is away from all other margins. The margins are inked as follow: deep-black, lateral-green, medial-blue, distal/inferior-red, proximal-superior-yellow. Cut section of the mass shows a heterogeneous yellow-tan section, with focal congestion. Some areas appear better differentiated with a yellowish color and a softer texture (approximately 50%); other ill-defined areas show a firm white texture. [REDACTED] submitted. Photographs are taken. Representative sections submitted.

Summary of sections:

TDM- tumor, in relation to deep margin
T-tumor
MLM- medial and lateral margins
SIM- superior and inferior margins
SK-skin

2.The specimen is received in formalin, labeled, "right arm mass", and consists of two fragments of tan yellow soft tissue, measuring 3.0 x 1.2 x 0.4 cm and 2.8x 1.5 x 0.4 cm. Specimen is entirely submitted.

Summary of sections:
U undesignated

Summary of Sections:

Part 1: Right arm mass

Block	Sect.	Site	PCs
1		MLM	1
1		SIM	1
1		SK	1
4		T	4
2		TDM	2

Part 2: Right arm mass

Block	Sect.	Site	PCs
2		U	2

** End of Report **

Source: NCI Genomic Data Commons file cb8570d8-bd2f-42e1-a5c8-45a3707e6e3e (TCGA-DX-A3LT.777C388E-7BDD-4E05-A531-A5AF510D6076.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).